Surgical pathology report (de-identified scan), TCGA case TCGA-CI-6623, project TCGA-READ (Rectum Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-CI-6623-01B (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: GASTROESOPHAGEAL JUNCTION, BIOPSY

A. REACTIVE SQUAMOUS AND GASTRIC TYPE MUCOSA.

B. NEGATIVE FOR INTESTINAL METAPLASIA.

PART 2: RECTUM, MASS, BIOPSY

INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA.

Date of Event ..

TCGA-CI-6623

Source: NCI Genomic Data Commons file 6137e0a1-37ad-4bd6-8c1b-edc22d3ba80f (TCGA-CI-6623.7BDB59AD-90F4-4FBA-8053-1DAF9945B869.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).